Somatic mutation profile of tumor specimen TCGA-X6-A8C5-01A (aliquot TCGA-X6-A8C5-01A-11D-A36J-09) from TCGA case TCGA-X6-A8C5, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 63.9 years (23,350 days).
Specimen TCGA-X6-A8C5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 983a4be5-1543-429a-8403-65eff6e736d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A8C5-10A (Blood Derived Normal), aliquot TCGA-X6-A8C5-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f13bb6f0-8468-495c-bb19-5720639680ce

The open-access MAF lists 60 somatic variants for this specimen: 50 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 9, Nonsense Mutation 3, Splice Region 2, Splice Site 1, Frame Shift Del 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABCA4 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1157062089, COSV64676383; called by muse, mutect2, varscan2
- ADAMTS20 | c.3031C>T p.R1011* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as rs200767698; called by muse, mutect2, varscan2
- AKNA | c.2317G>C p.E773Q | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV99800517; called by muse, mutect2
- ALPL | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs766948855, COSV100876902, COSV66379384; called by muse, mutect2, varscan2
- ATP1A2 | c.1631G>C p.G544A | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100767888; called by muse, mutect2, varscan2
- BAHCC1 | c.2566G>A p.V856M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (1); PolyPhen possibly damaging (0.509); catalogued as COSV57034524; called by muse, mutect2, varscan2
- BRSK2 | c.1098C>G p.D366E | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100372811; called by muse, mutect2, varscan2
- CAD | c.5883G>A p.K1961= | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99255190; called by muse, mutect2, varscan2
- CCDC87 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100040030; called by muse, mutect2, varscan2
- CNR1 | c.1332G>T p.R444S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV62986707; called by muse, mutect2, varscan2
- CTNNA2 | c.776A>C p.Q259P | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100784719; called by muse, mutect2, varscan2
- DNAH7 | c.11041T>A p.Y3681N | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100415621; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1055C>G p.A352G (on ENST00000361735 / NM_015935.5; = p.A266G on NM_014955.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV100675894; called by muse, mutect2, varscan2
- FAM53A | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.894); catalogued as COSV100357088; called by muse, mutect2, varscan2
- HID1 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs566625537, COSV100172873, COSV59351020; called by muse, mutect2, varscan2
- HTR6 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.836); catalogued as rs201177761, COSV99230234; called by muse, mutect2, varscan2
- KBTBD8 | c.198C>A p.N66K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.733); catalogued as COSV99805712; called by muse, mutect2, varscan2
- KRT23 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs920811846, COSV52929519; called by muse, mutect2, varscan2
- MEDAG | c.321G>T p.R107S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100995273; called by muse, mutect2, varscan2
- MFHAS1 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV99359646; called by muse, mutect2, varscan2
- MKRN3 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100091282; called by muse, mutect2, varscan2
- MYO5B | c.1817A>T p.K606M | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV99545284; called by muse, mutect2, varscan2
- NRXN1 | c.3721C>T p.R1241C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60485335; called by muse, mutect2, varscan2
- OR6C2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV100498718; called by muse, mutect2, varscan2
- PDE5A | c.150C>T p.T50= | Splice Region (SNP) | VAF 32/80 reads (40%) | catalogued as COSV99308798; called by muse, mutect2, varscan2
- PIGN | c.2647G>A p.G883S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777254701, COSV100715927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE | c.968C>G p.T323S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV100267071, COSV57675050; called by muse, mutect2, varscan2
- RAB4A | c.266C>G p.A89G | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV100797060; called by muse, mutect2, varscan2
- RPRD1A | c.553C>A p.Q185K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100036260; called by muse, varscan2
- RTL5 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV101030156; called by muse, mutect2, varscan2
- RTL5 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1296635045, COSV101030158; called by muse, mutect2
- SGO2 | c.2628T>A p.C876* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100764697; called by muse, mutect2, varscan2
- SLC4A1 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV99293386; called by muse, mutect2, varscan2
- SPTAN1 | c.5258C>T p.A1753V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1448733248, COSV100823651; called by muse, mutect2, varscan2
- SUPT20H | c.527A>G p.D176G (on ENST00000350612 / NM_001014286.3; = p.D177G on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010607998, COSV100634715; called by muse, mutect2, varscan2
- SYCP2L | c.2350G>T p.V784F | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99305311; called by muse, mutect2, varscan2
- TIAL1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as COSV100958358; called by muse, mutect2, varscan2
- TLR4 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.164); catalogued as COSV100790594; called by muse, mutect2, varscan2
- TRHDE | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV99671180; called by muse, mutect2, varscan2
- UBQLNL | c.40A>G p.S14G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as COSV100974569; called by muse, mutect2, varscan2
- XAB2 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100601726; called by muse, mutect2, varscan2
- ZNF700 | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369385189, COSV99583574; called by muse, mutect2, varscan2
- COL22A1 | c.1977+1del p.X659_splice | Splice Site (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- DNMT1 | c.2672A>T p.K891I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- GALNTL6 | c.98A>T p.D33V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2
- GEMIN2 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2
- GMIP | c.1492_1500del p.R498_R500del | In Frame Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- PTGER2 | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.298); called by muse, varscan2
- PTGER2 | c.1069_1073del p.D357Lfs*6 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | called by pindel, varscan2
- AOPEP | c.499C>T p.L167= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV52923612; called by muse, mutect2, varscan2
- DNAAF1 | c.1272G>A p.S424= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs772170131, COSV57576413; called by muse, mutect2, varscan2
- EFL1 | c.1923C>T p.N641= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV99187304; called by muse, mutect2, varscan2
- IFNL1 | c.504T>A p.S168= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as COSV100373653; called by muse, mutect2, varscan2
- IQCA1 | c.612G>A p.V204= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99609700; called by muse, mutect2, varscan2
- PLK4 | c.2007C>T p.N669= | Silent (SNP) | VAF 99/247 reads (40%) | catalogued as COSV54636704, COSV99584689; called by muse, mutect2, varscan2
- RADX | c.2232C>T p.S744= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs140805762, COSV65319535; called by muse, mutect2, varscan2
- STK10 | c.186T>C p.A62= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV99451701; called by muse, mutect2, varscan2
- VCX3A | c.135T>G p.V45= | Silent (SNP) | VAF 12/72 reads (17%) | called by mutect2, varscan2
- PITPNC1 | c.683-5463T>A | Intron (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100083571, COSV55456821; called by muse, mutect2, varscan2
